Somatic mutation profile of tumor specimen TCGA-BR-8487-01A (aliquot TCGA-BR-8487-01A-11D-2394-08) from TCGA case TCGA-BR-8487, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 64.1 years (23,400 days).
Specimen TCGA-BR-8487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a02ae53-49e0-4d94-b9ac-5e93cd5a8368.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8487-10A (Blood Derived Normal), aliquot TCGA-BR-8487-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42158193-ca69-48ba-9b7c-bfd7763a144c

The open-access MAF lists 3,388 somatic variants for this specimen: 2,591 protein-altering or splice-affecting, 727 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,779, Silent 727, Frame Shift Del 557, Nonsense Mutation 90, Frame Shift Ins 87, Splice Site 37, Splice Region 26, Intron 26, RNA 20, In Frame Del 12, 3'UTR 10, 5'Flank 5.

Variants (750 of 3,388; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as rs121434359, CM086763, COSV54355274; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs281875299, CM044563, COSV63021386; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- B2M | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1057519877, COSV62562849, COSV62563168, COSV62564729; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRWD3 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs1057518650, COSV64748656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.377T>A p.V126D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs104894098, CM940231, COSV58684293, COSV58705336; ClinVar: pathogenic / risk factor; called by muse, mutect2, varscan2
- CFTR | c.2502del p.F834Lfs*10 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as rs397508389, COSV50077164; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- COL11A2 | c.966del p.T323Qfs*59 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs748440351, COSV59498865; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- COL13A1 | c.621del p.G208Efs*15 (on ENST00000398978 / NM_001130103.2; = p.G170Efs*28 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs763281993; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DDX3X | c.1579C>T p.R527C (on ENST00000399959; = p.R528C on NM_001356.5) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1064795323, COSV67863221; ClinVar: likely pathogenic; called by muse, mutect2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ELN | c.590del p.G197Dfs*126 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs863223526; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 61/143 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FLG | c.477del p.E160Kfs*34 | Frame Shift Del (DEL) | VAF 30/69 reads (43%) | catalogued as rs746683647; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- HIVEP2 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as rs869312841, CM163425, COSV50014693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IQCB1 | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as rs866982675, CM110330, COSV60437680; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 62/130 reads (48%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MECP2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934907, CM023812, CM992175, COSV57654085; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MTHFR | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 77/204 reads (38%) | catalogued as rs121434294, CM941070, COSV64701757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NONO | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs869025345, CM1512177, COSV52137834; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP1 | c.555del p.K185Nfs*7 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs766524637, CD1511891; ClinVar: pathogenic; called by mutect2, varscan2
- PANK2 | c.1257del p.F419Lfs*31 (on ENST00000316562 / NM_153638.3; = p.F128Lfs*31 on NM_024960.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 50/133 reads (38%) | catalogued as rs1568574931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 35/69 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- SCN5A | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199473072, CM030951; ClinVar: not provided / likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2
- SLC25A22 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388811021, COSV57193430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TGFBR2 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 36/90 reads (40%) | catalogued as rs104893819, CM064334, COSV55443391, COSV55447248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VWF | c.2435del p.P812Rfs*31 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as rs62643632, CD920917, CM074633, COSV54614968; ClinVar: pathogenic; called by mutect2, pindel
- AAAS | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52933086; called by muse, mutect2
- AARS1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55747499; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 45/179 reads (25%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel, varscan2
- ABCA1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs550551082, COSV101036304, COSV66066827; called by muse, varscan2
- ABCA13 | c.11093T>C p.V3698A | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71285883; called by muse, mutect2, varscan2
- ABCA3 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs769313907, COSV57054086; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 38/58 reads (66%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCB11 | c.3676C>T p.R1226C | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772241929, COSV55591899; ClinVar: uncertain significance; called by muse, mutect2
- ABCB8 | c.1487C>T p.T496M (on ENST00000297504 / NM_001282291.2; = p.T479M on NM_007188.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs1229788875, COSV52505104; called by muse, mutect2, varscan2
- ABCC11 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs779714888, COSV62323348; called by muse, mutect2, varscan2
- ABCC3 | c.3013C>T p.Q1005* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as COSV53322532; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCC4 | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV65313072; called by muse, mutect2, varscan2
- ABL2 | c.3190G>T p.G1064C (on ENST00000502732 / NM_007314.4; = p.G1049C on NM_005158.5) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV61014703; called by muse, mutect2, varscan2
- ABL2 | c.1034T>C p.V345A (on ENST00000502732 / NM_007314.4; = p.V330A on NM_005158.5) | Missense Mutation (SNP) | VAF 97/148 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213899879, COSV61014711; called by muse, mutect2, varscan2
- AC011455.2 | c.1708T>C p.Y570H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55499841; called by muse, mutect2, varscan2
- ACAD10 | c.1970A>G p.E657G | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV58157703; called by muse, mutect2, varscan2
- ACAD11 | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53896649; called by muse, varscan2
- ACD | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV54667904; called by muse, mutect2
- ACE | c.3308del p.P1103Qfs*69 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs1447215842; called by mutect2, pindel, varscan2
- ACKR3 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.922); catalogued as rs776743438, COSV56021991, COSV56022941; called by muse, mutect2, varscan2
- ACMSD | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs376175166; called by muse, mutect2, varscan2
- ACSL3 | c.1293C>T p.S431= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as rs1403115254, COSV62482361; called by muse, mutect2, varscan2
- ACSM2B | c.1636T>C p.F546L | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61658023; called by muse, mutect2, varscan2
- ACTL6B | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.143); catalogued as COSV50515142; called by muse, mutect2, varscan2
- ACTL7A | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV61776758; called by muse, mutect2, varscan2
- ACTR1B | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs762467775, COSV56704467; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 42/60 reads (70%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS13 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as rs147201977, COSV100747080; called by muse, mutect2, varscan2
- ADAMTS15 | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54505962; called by muse, mutect2, varscan2
- ADAMTS18 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV51412828; called by muse, mutect2, varscan2
- ADAMTS2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371384169; called by muse, mutect2, varscan2
- ADAMTS6 | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV66858386; called by muse, mutect2, varscan2
- ADAMTSL2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242674081, COSV63204290; called by muse, mutect2, varscan2
- ADARB1 | c.1589C>T p.T530M (on ENST00000360697 / NM_001346687.2; = p.T490M on NM_001112.4) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770534585, COSV62344570; called by muse, mutect2, varscan2
- ADCY1 | c.3317C>A p.P1106Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.017); catalogued as COSV52035247; called by muse, mutect2, varscan2
- ADCY8 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV53909632; called by muse, mutect2, varscan2
- ADCY8 | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV53909649; called by muse, mutect2, varscan2
- ADCY9 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs144986362; called by muse, mutect2, varscan2
- ADCY9 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV53573046; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs533235753, COSV57073947; called by muse, mutect2, varscan2
- ADGRB2 | c.1676del p.P559Rfs*85 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV57077639, COSV99925963; called by mutect2, varscan2
- ADGRB2 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV57073960; called by muse, mutect2, varscan2
- ADGRL1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); catalogued as rs375084597, COSV61564845; called by muse, mutect2, varscan2
- ADH1B | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59296617; called by muse, mutect2, varscan2
- ADH1C | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs370818269; called by muse, mutect2, varscan2
- ADH1C | c.547T>A p.S183T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV72463481; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 53/129 reads (41%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- AEBP1 | c.1462T>C p.Y488H | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV56258216; called by muse, mutect2, varscan2
- AEN | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561034272, COSV60429437; called by muse, mutect2, varscan2
- AFF2 | c.839T>C p.M280T | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV60666084; called by muse, mutect2, varscan2
- AFF2 | c.1266G>A p.M422I | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781885980, COSV53991083; called by muse, mutect2
- AFF3 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV57855545; called by muse, mutect2
- AFMID | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372327612; called by muse, mutect2, varscan2
- AGAP1 | c.1589G>A p.R530Q (on ENST00000304032 / NM_001037131.3; = p.R477Q on NM_014914.5) | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs3207207; called by muse, mutect2, varscan2
- AGAP1 | c.2537G>A p.R846Q (on ENST00000304032 / NM_001037131.3; = p.R793Q on NM_014914.5) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs544625578, COSV58327072; called by muse, mutect2, varscan2
- AGAP3 | c.2036G>A p.R679H (on ENST00000622464; = p.R715H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750679955, COSV68244885; called by muse, mutect2, varscan2
- AGAP6 | c.1529C>T p.S510L (on ENST00000374056 / NM_001365867.1; = p.S533L on NM_001077665.2) | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV100929166; called by muse, mutect2, varscan2
- AGBL1 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as rs777333054, COSV66859300; called by muse, mutect2, varscan2
- AGO2 | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as COSV55047873; called by muse, mutect2, varscan2
- AGRN | c.2289del p.L764Yfs*99 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as COSV65070612; called by mutect2, pindel, varscan2
- AGRN | c.4382G>A p.R1461Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1451237583, COSV65069791; called by muse, mutect2, varscan2
- AHCTF1 | c.170C>T p.A57V (on ENST00000366508; = p.A31V on NM_015446.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100404483; called by mutect2, varscan2
- AHDC1 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.912); catalogued as rs747778584, COSV55939151; called by muse, mutect2, varscan2
- AHNAK | c.3393G>A p.M1131I | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs375126350, COSV57209502; called by muse, mutect2, varscan2
- AHNAK2 | c.16909C>T p.P5637S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV60916551; called by muse, mutect2, varscan2
- AK8 | c.973A>C p.M325L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.062); catalogued as COSV53754927; called by muse, mutect2, varscan2
- AK9 | c.351A>G p.I117M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as COSV53421370; called by muse, mutect2, varscan2
- AKAP17A | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV58308831; called by muse, mutect2, varscan2
- AKAP3 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); catalogued as COSV57417106; called by muse, mutect2, varscan2
- AKAP6 | c.1909C>A p.L637I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55215026; called by muse, mutect2, varscan2
- AKAP6 | c.2894A>T p.D965V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55215035; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKAP9 | c.10966A>G p.N3656D (on ENST00000359028; = p.N3632D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV62347305; called by muse, mutect2, varscan2
- AKR1D1 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs747940247, COSV54337737; called by muse, mutect2, varscan2
- AKR7A3 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV64389277; called by muse, mutect2, varscan2
- AL031777.2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.748); catalogued as rs146180063, COSV61911971; called by mutect2, varscan2
- ALAS1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59627385; called by muse, mutect2, varscan2
- ALCAM | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60248858; called by muse, mutect2, varscan2
- ALDH5A1 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as rs748170674, CM033327, COSV62373689; called by muse, mutect2, varscan2
- ALG12 | c.768+1del p.X256_splice | Splice Site (DEL) | VAF 18/101 reads (18%) | catalogued as rs762397075, COSV58206565; called by mutect2, pindel, varscan2
- ALG6 | c.1508A>G p.Q503R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1056967570, COSV99586351; called by muse, mutect2, varscan2
- ALKBH2 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV57449007; called by muse, mutect2, varscan2
- ALPK1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188866014; called by muse, mutect2, varscan2
- ALPK2 | c.2518A>G p.T840A | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV64493417; called by muse, mutect2
- ALPK3 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs962690116, COSV51933891; called by muse, mutect2
- ALS2CL | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1180484664, COSV59670528, COSV59672050; called by muse, mutect2, varscan2
- AMACR | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs763403225, COSV59461226; called by muse, mutect2, varscan2
- AMPD2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs765794204, COSV56648064; called by muse, mutect2, varscan2
- AMTN | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV59489102; called by muse, mutect2, varscan2
- ANAPC10 | c.542A>T p.Y181F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as COSV58739659; called by muse, mutect2, varscan2
- ANGPT2 | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57337237; called by muse, varscan2
- ANK3 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55060045; called by muse, mutect2, varscan2
- ANKAR | c.1270T>C p.Y424H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55613120; called by muse, mutect2, varscan2
- ANKIB1 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV56061881; called by muse, mutect2, varscan2
- ANKMY1 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as COSV56034780; called by muse, mutect2
- ANKRD13A | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55675585; called by muse, mutect2
- ANKRD29 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52426022; called by muse, mutect2, varscan2
- ANKRD6 | c.2016del p.F672Lfs*34 (on ENST00000339746 / NM_001242809.2; = p.F667Lfs*34 on NM_014942.4) | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs751514998, COSV100329734; called by mutect2, pindel, varscan2
- ANKS1B | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV61352778; called by muse, mutect2, varscan2
- ANO4 | c.929C>T p.T310I (on ENST00000392977 / NM_001286615.2; = p.T275I on NM_178826.4) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as COSV54597158; called by muse, mutect2
- AOC1 | c.1471A>G p.T491A | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.168); catalogued as COSV62868884; called by muse, mutect2, varscan2
- AOC1 | c.2009C>T p.T670M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368330728; called by muse, mutect2, varscan2
- AOC3 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.113); catalogued as COSV53826814; called by muse, mutect2, varscan2
- AP001781.2 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV52788571; called by muse, mutect2, varscan2
- AP001781.2 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52788610; called by muse, mutect2, varscan2
- AP2A1 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV62818859; called by muse, mutect2
- AP5Z1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs534552849, COSV62241991; called by muse, mutect2, varscan2
- AP5Z1 | c.2134A>G p.S712G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62242007; called by muse, mutect2
- APBB3 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776216532, COSV60052541; called by muse, mutect2, varscan2
- APC | c.1552A>G p.T518A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.613); catalogued as COSV57346956; called by muse, mutect2, varscan2
- APCDD1L | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV64486460; called by muse, mutect2
- APOA1 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as CD991585, COSV52635806; called by muse, mutect2, varscan2
- APOA4 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs754506873, COSV100759398; called by muse, mutect2, varscan2
- APOB | c.4905A>C p.K1635N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV51937099; called by muse, mutect2, varscan2
- APOB | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV51937110; called by muse, mutect2, varscan2
- APOH | c.388T>C p.W130R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52772870; called by muse, mutect2, varscan2
- APOH | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52772880; called by muse, mutect2, varscan2
- APOLD1 | c.761G>A p.R254Q (on ENST00000326765 / NM_001130415.2; = p.R223Q on NM_030817.3) | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as rs1489204217, COSV58732878; called by muse, mutect2, varscan2
- AQP10 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV59246307; called by muse, mutect2, varscan2
- AQP3 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53048404; called by muse, mutect2, varscan2
- AQP8 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54845524; called by muse, mutect2, varscan2
- AQR | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV99334779; called by muse, mutect2, varscan2
- ARAF | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs765113993, COSV51692898; called by muse, varscan2
- ARAP1 | c.3721G>A p.V1241M (on ENST00000393609 / NM_001040118.2; = p.V996M on NM_015242.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61991361; called by muse, mutect2, varscan2
- ARAP1 | c.1023-2A>G p.X341_splice (on ENST00000393609 / NM_001040118.2; = p.X96_splice on NM_015242.4) | Splice Site (SNP) | VAF 13/61 reads (21%) | catalogued as COSV61991368; called by muse, mutect2, varscan2
- ARAP2 | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs376907114; called by muse, mutect2, varscan2
- ARAP2 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); catalogued as COSV58287244; called by muse, mutect2, varscan2
- ARAP2 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs764324173, COSV58287254; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 76/150 reads (51%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARFGEF2 | c.2030A>G p.D677G | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1292390703, COSV64212607; called by muse, mutect2, varscan2
- ARHGAP27 | c.2422C>T p.R808C (on ENST00000428638 / NM_001282290.1; = p.R467C on NM_199282.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1181718358, COSV65357854; called by muse, mutect2
- ARHGAP29 | c.2109G>T p.Q703H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53112378; called by muse, mutect2, varscan2
- ARHGAP30 | c.3284C>A p.P1095H (on ENST00000368013 / NM_001025598.2; = p.P884H on NM_181720.3) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV63516775; called by muse, mutect2, varscan2
- ARHGAP45 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs571895313, COSV54024447, COSV54024651; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARHGEF10 | c.1451C>T p.A484V (on ENST00000398564; = p.A459V on NM_014629.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs144726787; called by muse, mutect2, varscan2
- ARHGEF10L | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV51433171; called by muse, mutect2, varscan2
- ARHGEF10L | c.3071G>C p.S1024T | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.917); catalogued as COSV51433217; called by muse, mutect2, varscan2
- ARHGEF12 | c.3986G>A p.R1329Q | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs770268450, COSV100755005, COSV63104928; called by muse, mutect2, varscan2
- ARHGEF16 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.022); catalogued as rs765283215, COSV65682140; called by muse, mutect2, varscan2
- ARHGEF40 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53880688; called by muse, mutect2, varscan2
- ARHGEF40 | c.2902C>T p.R968W | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs201584278; called by muse, varscan2
- ARHGEF7 | c.67del p.T23Pfs*13 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | catalogued as rs754827718; called by mutect2, pindel, varscan2
- ARID1A | c.2201A>G p.D734G | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV61378393; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 37/121 reads (31%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARIH2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62704889; called by muse, mutect2, varscan2
- ARL6IP4 | c.1194_1195del p.H398Qfs*51 (on ENST00000315580 / NM_018694.3; = p.H379Qfs*51 on NM_016638.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs759023993; called by pindel, varscan2
- ARPP21 | c.1574A>G p.Q525R | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV51798594; called by muse, mutect2, varscan2
- ASB15 | c.1078A>G p.N360D | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926231; called by muse, mutect2, varscan2
- ASB5 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56671004; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | catalogued as rs761154268; called by mutect2, varscan2
- ASH1L | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 65/118 reads (55%) | catalogued as COSV64208381; called by muse, mutect2, varscan2
- ASPM | c.8705A>G p.Q2902R | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV54130489; called by muse, mutect2, varscan2
- ASTL | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60904374; called by muse, mutect2, varscan2
- ASTN2 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs769734450, COSV57781185; called by muse, mutect2, varscan2
- ASTN2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV57781195; called by muse, mutect2, varscan2
- ASXL2 | c.4178T>C p.I1393T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1402223554, COSV55459435; called by muse, mutect2, varscan2
- ATG2B | c.3363C>T p.G1121= | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as COSV55890501; called by muse, mutect2
- ATG9B | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52505095; called by muse, mutect2, varscan2
- ATP10A | c.3996G>T p.K1332N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63517910, COSV63519586; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 176/489 reads (36%) | catalogued as rs35191129; called by mutect2, pindel, varscan2
- ATP1A4 | c.945del p.F315Lfs*38 | Frame Shift Del (DEL) | VAF 78/284 reads (27%) | catalogued as rs1218175053; called by mutect2, varscan2
- ATP2A1 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 49/106 reads (46%) | catalogued as rs201738416, COSV62869617; called by muse, mutect2, varscan2
- ATP2B2 | c.782-1G>T p.X261_splice | Splice Site (SNP) | VAF 65/158 reads (41%) | catalogued as COSV59497334; called by muse, mutect2, varscan2
- ATP2B3 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs373144811, COSV54848526; called by muse, mutect2, varscan2
- ATP2C1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs141384562; called by muse, mutect2, varscan2
- ATP7A | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1057523112, COSV58446785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7A | c.3061C>T p.Q1021* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV58446796; called by muse, mutect2, varscan2
- ATP8B4 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52716240; called by muse, mutect2, varscan2
- ATP9A | c.2593T>C p.Y865H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV58767019; called by muse, mutect2, varscan2
- ATR | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.623); catalogued as rs367641692; called by muse, mutect2, varscan2
- AURKA | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs375420005; called by muse, mutect2, varscan2
- AXL | c.2102A>G p.D701G (on ENST00000301178 / NM_021913.5; = p.D692G on NM_001699.6) | Missense Mutation (SNP) | VAF 130/233 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56568759; called by muse, mutect2, varscan2
- B3GAT1 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230804401, COSV56995133, COSV56997668; called by muse, mutect2, varscan2
- B3GLCT | c.1196G>A p.S399N | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58455539; called by muse, mutect2, varscan2
- B3GNT4 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1161545178, COSV57336455; called by muse, mutect2, varscan2
- B4GALT7 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV50353434; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1265G>A p.S422N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs76206450; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs201216387, COSV57635515; called by muse, mutect2, varscan2
- BAIAP3 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV60980440; called by muse, mutect2, varscan2
- BBS12 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV58562170; called by muse, mutect2, varscan2
- BBS7 | c.1847A>G p.Q616R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV52656789; called by muse, mutect2, varscan2
- BCAM | c.590A>G p.E197G | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as COSV54302533; called by muse, mutect2, varscan2
- BCAM | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as rs755899513, COSV54300693; called by muse, mutect2, varscan2
- BCAR1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV50784168; called by muse, mutect2, varscan2
- BCKDK | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); catalogued as rs751842287, COSV54892072; called by muse, mutect2, varscan2
- BCL11A | c.875C>T p.T292M (on ENST00000335712 / NM_001365609.1; = p.T326M on NM_018014.4) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV59630708; called by muse, mutect2, varscan2
- BCL2 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as COSV61380190; called by muse, mutect2
- BCL2L13 | c.741G>A p.W247* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | catalogued as COSV58225929; called by muse, mutect2
- BCOR | c.187A>G p.R63G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60708099; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 22/98 reads (22%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BCR | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59931648; called by muse, mutect2, varscan2
- BDNF | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV59235442; called by muse, mutect2
- BEND3 | c.2285A>G p.N762S | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs782224084, COSV64681106; called by muse, mutect2, varscan2
- BEND3 | c.1787A>G p.N596S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV64681109; called by muse, mutect2, varscan2
- BEST3 | c.870A>G p.V290= | Splice Region (SNP) | VAF 20/53 reads (38%) | catalogued as COSV58301834; called by muse, mutect2, varscan2
- BEST4 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as rs777990349, COSV64733985; called by muse, mutect2, varscan2
- BICD1 | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as rs761440526, COSV55679869; called by muse, mutect2, varscan2
- BICRAL | c.2454G>T p.E818D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58405865; called by muse, mutect2, varscan2
- BIN1 | c.692G>A p.W231* (on ENST00000316724 / NM_001320642.1; = p.W200* on NM_004305.4) | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV52118801; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs776003776; called by mutect2, varscan2
- BIRC3 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV54817118; called by muse, mutect2, varscan2
- BIRC6 | c.7318G>A p.A2440T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV70199719; called by muse, mutect2
- BMP2K | c.1791T>C p.N597= | Splice Region (SNP) | VAF 10/51 reads (20%) | catalogued as rs771503766, COSV58595587; called by muse, mutect2, varscan2
- BMP2K | c.2636A>G p.N879S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1303553012, COSV55009898; called by muse, mutect2, varscan2
- BMP7 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1390807710, COSV67780914; called by muse, mutect2, varscan2
- BMPER | c.1162T>C p.Y388H | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51819694; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMS1 | c.3587C>T p.P1196L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs201022846, COSV65734003; called by muse, mutect2, varscan2
- BNC2 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs751961896, COSV66148194; called by muse, mutect2, varscan2
- BNIP5 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV71325561, COSV71325730; called by muse, mutect2, varscan2
- BORA | c.1039A>G p.I347V (on ENST00000613797; = p.I272V on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV64695295; called by muse, mutect2, varscan2
- BORA | c.1300G>T p.G434C (on ENST00000613797; = p.G359C on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV64695164; called by muse, mutect2, varscan2
- BPGM | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs771037885, COSV61324703; called by muse, mutect2, varscan2
- BPIFC | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.736); catalogued as COSV55912691; called by muse, mutect2, varscan2
- BPNT1 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); catalogued as COSV59039998; called by muse, mutect2, varscan2
- BRD1 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53457741; called by muse, mutect2, varscan2
- BRD3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57703049; called by muse, mutect2, varscan2
- BRD4 | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54586784, COSV54596856; called by muse, mutect2, varscan2
- BRD7 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325340063, COSV67158465, COSV67158877; called by muse, mutect2, varscan2
- BRINP3 | c.1118T>A p.V373E | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV66513032, COSV66525484; called by muse, varscan2
- BRINP3 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778586472, COSV66525489; called by muse, varscan2
- BRPF1 | c.2754G>T p.Q918H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.187); catalogued as COSV57405127; called by muse, mutect2, varscan2
- BTBD1 | c.693C>G p.D231E | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.969); catalogued as rs144730017; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD2 | c.1557del p.E520Rfs*20 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs1568213070; called by mutect2, pindel, varscan2
- BTBD2 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as COSV55309012; called by muse, mutect2, varscan2
- BTBD6 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV59265856, COSV59266936; called by muse, mutect2, varscan2
- BTK | c.993A>G p.I331M | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV58120247; called by muse, mutect2, varscan2
- BUB1B | c.2176T>C p.Y726H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV55013013; called by muse, mutect2, varscan2
- C14orf39 | c.1349del p.P450Rfs*27 | Frame Shift Del (DEL) | VAF 39/171 reads (23%) | catalogued as COSV58783855; called by mutect2, pindel, varscan2
- C16orf90 | c.467del p.Q157Sfs*113 (on ENST00000399645 / NM_001353385.2; = p.Q148Sfs*113 on NM_001080524.2) | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV101290973; called by mutect2, pindel, varscan2
- C19orf54 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs375933809; called by muse, mutect2, varscan2
- C19orf57 | c.1224del p.G409Afs*4 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | catalogued as rs35608314; called by mutect2, pindel
- C1QA | c.668del p.K223Rfs*59 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs1433567552; called by mutect2, pindel, varscan2
- C1QTNF3 | c.693C>G p.H231Q | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV51468812; called by muse, mutect2, varscan2
- C1orf112 | c.756T>G p.F252L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV53676401, COSV53679212; called by muse, mutect2, varscan2
- C1orf56 | c.182G>T p.R61M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV54847132; called by muse, mutect2, varscan2
- C20orf194 | c.3232A>G p.K1078E | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52696371; called by muse, varscan2
- C2CD3 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs1406007301, CD164515; called by mutect2, pindel, varscan2
- C2orf68 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs369719783; called by muse, mutect2, varscan2
- C5AR2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57256368; called by muse, mutect2, varscan2
- C5orf34 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60930267; called by muse, mutect2
- C6orf118 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.887); catalogued as rs201539458, COSV57815326; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C9 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200646202; called by muse, mutect2, varscan2
- CA13 | c.327A>G p.I109M | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58797933; called by muse, mutect2, varscan2
- CA9 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65675762; called by muse, mutect2, varscan2
- CACHD1 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV51553834; called by muse, mutect2, varscan2
- CACNA1A | c.4805G>A p.R1602Q | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV64199174; called by muse, mutect2, varscan2
- CACNA1A | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943419160, COSV100802623, COSV64198810; called by muse, mutect2
- CACNA1C | c.1358A>G p.D453G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.411); catalogued as COSV100222578; called by muse, mutect2, varscan2
- CACNA1D | c.2593G>A p.A865T (on ENST00000350061 / NM_001128840.3; = p.A885T on NM_000720.4) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs991138935, COSV55438497, COSV55448418; called by muse, mutect2, varscan2
- CACNA1D | c.6212T>C p.L2071S (on ENST00000350061 / NM_001128840.3; = p.L2091S on NM_000720.4) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV55448431; called by muse, mutect2, varscan2
- CACNA1E | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs1428423503, COSV62397535; called by muse, mutect2, varscan2
- CACNA1E | c.5671G>T p.E1891* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV62397553; called by muse, mutect2, varscan2
- CACNA1G | c.4765C>A p.Q1589K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV61728591; called by muse, mutect2, varscan2
- CACNA1H | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764277325, COSV61991615; called by muse, mutect2, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CACNA1H | c.6913C>T p.P2305S | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs553649904, COSV52354881, COSV52357451; called by muse, mutect2, varscan2
- CACNG8 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV54414878; called by muse, mutect2, varscan2
- CADM4 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55928933; called by muse, mutect2, varscan2
- CADPS | c.1781A>G p.N594S | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV51881704; called by muse, mutect2, varscan2
- CALD1 | c.1516A>G p.T506A (on ENST00000361675 / NM_033138.4; = p.T251A on NM_004342.7) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV62648262; called by muse, varscan2
- CAMSAP2 | c.2911C>T p.P971S (on ENST00000236925 / NM_001297707.2; = p.P960S on NM_203459.3) | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs562531178, COSV52671262; called by muse, mutect2, varscan2
- CAPN11 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV67237704; called by muse, mutect2, varscan2
- CAPN11 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs760516367, COSV67237709; called by muse, mutect2, varscan2
- CAPN7 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53778405; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARMIL3 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as rs761025705, COSV57726617; called by muse, mutect2, varscan2
- CASKIN1 | c.2938C>T p.R980W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs755492319, COSV58214662; called by muse, mutect2, varscan2
- CASP10 | c.97del p.V33Sfs*12 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs1559292087, COSV53780006; called by mutect2, pindel, varscan2
- CASP5 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52828871; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 42/90 reads (47%) | catalogued as rs765105588; called by mutect2, varscan2
- CASP8 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV51851519; called by muse, mutect2, varscan2
- CAVIN3 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as COSV58268969; called by muse, mutect2, varscan2
- CBLC | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV54322801; called by muse, mutect2, varscan2
- CBLN4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1238533417, COSV50353030; called by muse, mutect2
- CBX6 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53320933; called by muse, varscan2
- CBX7 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs746842819, COSV53358276, COSV53358982; called by muse, mutect2, varscan2
- CCDC130 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55583515; called by muse, mutect2
- CCDC136 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773067584, COSV52799940; called by muse, mutect2, varscan2
- CCDC158 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as rs753263337, COSV66356101; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC186 | c.2255A>G p.N752S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV65161297; called by muse, mutect2, varscan2
- CCDC40 | c.783_784del p.R261Sfs*7 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as rs757076408; called by pindel, varscan2
- CCDC40 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs185083705, COSV53899963; called by muse, mutect2
- CCDC61 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200544702; called by muse, varscan2
- CCDC80 | c.2147T>C p.L716P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52817104; called by muse, mutect2, varscan2
- CCDC81 | c.1885C>T p.R629C (on ENST00000445632 / NM_001156474.2; = p.R539C on NM_021827.4) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs756085576, COSV53578732; called by muse, mutect2, varscan2
- CCDC88B | c.3458G>A p.G1153D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV57266341; called by muse, mutect2, varscan2
- CCDC88B | c.3938G>A p.G1313D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57266351, COSV57266474; called by muse, mutect2, varscan2
- CCDC88C | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.147); catalogued as COSV66238389; called by muse, mutect2, varscan2
- CCDC92 | c.302A>G p.E101G | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53019945; called by muse, mutect2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs765438623; called by pindel, varscan2
- CCN2 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.456); catalogued as rs371266547, COSV63466730; called by muse, varscan2
- CCNI2 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as COSV51524048; called by muse, mutect2, varscan2
- CCNT1 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56064358; called by muse, mutect2, varscan2
- CCRL2 | c.985T>C p.S329P | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs781703263, COSV62193538; called by muse, mutect2, varscan2
- CCSER1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV61434243; called by muse, mutect2, varscan2
- CCT6A | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV51905789; called by muse, mutect2, varscan2
- CD163 | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as COSV63132740; called by muse, mutect2, varscan2
- CD69 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57302842; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC16 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245057409, COSV52960886; called by muse, varscan2
- CDC27 | c.1487A>G p.Y496C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs76995821, COSV50366319; called by muse, mutect2, varscan2
- CDC42SE2 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.791); catalogued as rs373834432; called by muse, mutect2, varscan2
- CDH12 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs546440934, COSV66407741; called by muse, mutect2, varscan2
- CDH13 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs771613971, COSV51823582, COSV99231844; called by muse, mutect2, varscan2
- CDH15 | c.2036G>A p.S679N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.163); catalogued as COSV57024701; called by muse, mutect2, varscan2
- CDH20 | c.1525G>T p.G509* | Nonsense Mutation (SNP) | VAF 38/105 reads (36%) | catalogued as COSV53010540; called by muse, mutect2, varscan2
- CDH23 | c.10021C>T p.R3341C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs370074117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 43/115 reads (37%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDH5 | c.2230A>G p.S744G | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478563013, COSV58517740; called by muse, mutect2, varscan2
- CDK13 | c.4409C>T p.P1470L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.84); catalogued as rs776784082, COSV51700315; called by muse, mutect2, varscan2
- CDK18 | c.877C>T p.H293Y (on ENST00000506784 / NM_212503.3; = p.H263Y on NM_002596.4) | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63727617; called by muse, mutect2, varscan2
- CDK5R1 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1032779285, COSV55578984; called by muse, mutect2, varscan2
- CDKL4 | c.357A>G p.I119M | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV66509711; called by muse, mutect2
- CDKN2AIP | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as rs754705709, COSV100187643, COSV56627264; called by muse, mutect2, varscan2
- CDRT1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1201781215, COSV55411865, COSV55413232; called by muse, mutect2, varscan2
- CEACAM1 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs1310422690, COSV50727882; called by muse, mutect2
- CEL | c.1391A>G p.Y464C (on ENST00000673714; = p.Y461C on NM_001807.6) | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60827495; called by muse, mutect2, varscan2
- CELF4 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs769180157, COSV58452460; called by muse, mutect2, varscan2
- CELSR2 | c.8767C>T p.H2923Y | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1291388409, COSV54772597; called by muse, mutect2, varscan2
- CELSR3 | c.5537G>A p.G1846D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50865919; called by muse, mutect2, varscan2
- CEMIP2 | c.1400del p.P467Lfs*10 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as COSV100987198, COSV100987531; called by mutect2, pindel
- CENPBD1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV51919322; called by muse, mutect2, varscan2
- CEP120 | c.2154C>A p.D718E | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV60265720; called by muse, mutect2, varscan2
- CEP131 | c.2350C>T p.Q784* (on ENST00000269392 / NM_001319228.2; = p.Q781* on NM_014984.4) | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV53953326; called by muse, mutect2, varscan2
- CEP135 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs192961697; called by muse, mutect2, varscan2
- CEP192 | c.4814G>A p.S1605N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV58064826; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs747064410; called by mutect2, varscan2
- CEP97 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs144348649; called by muse, mutect2, varscan2
- CEPT1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as rs752416064, COSV64111047; called by muse, mutect2, varscan2
- CERS1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs1245703626, COSV55929456; called by muse, mutect2
- CERS6 | c.394T>C p.F132L | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV59830623; called by muse, mutect2, varscan2
- CERT1 | c.767G>A p.R256H (on ENST00000405807 / NM_001130105.1; = p.R128H on NM_005713.3) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs372235292; called by muse, mutect2, varscan2
- CES4A | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV58653577; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP46 | c.5971G>A p.G1991S | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs541680936, COSV99584532, COSV99585634; called by muse, mutect2, varscan2
- CFAP65 | c.3700G>A p.D1234N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58561494; called by muse, mutect2, varscan2
- CFAP74 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs541722655, COSV54568277; called by muse, mutect2, varscan2
- CFAP97 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57110535; called by muse, mutect2, varscan2
- CFHR1 | c.632del p.P211Lfs*39 | Frame Shift Del (DEL) | VAF 60/165 reads (36%) | catalogued as COSV57627802; called by mutect2, pindel, varscan2
- CFL2 | c.70_72del p.S24del | In Frame Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs774697837; called by pindel, varscan2
- CFTR | c.1478A>C p.Q493P | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397508214, CM024232, CM090069, CM940252, COSV50056706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGAS | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64808233; called by muse, mutect2, varscan2
- CGB7 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.279); catalogued as rs760391152, COSV100655135; called by muse, mutect2, varscan2
- CHD4 | c.2075C>T p.T692I (on ENST00000357008 / NM_001363606.2; = p.T705I on NM_001273.5) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV58901780; called by muse, mutect2, varscan2
- CHD6 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58557509; called by muse, mutect2, varscan2
- CHD8 | c.1520C>T p.A507V (on ENST00000646647 / NM_001170629.2; = p.A228V on NM_020920.4) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV67870682; called by muse, mutect2, varscan2
- CHIT1 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 104/175 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55146502, COSV55147142; called by muse, mutect2, varscan2
- CHMP2B | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1178304983, COSV55462127; called by muse, mutect2
- CHRNA10 | c.1256G>T p.W419L | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51704799; called by muse, mutect2, varscan2
- CHRNA10 | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709521; called by muse, mutect2
- CHRNA2 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV53557865; called by muse, mutect2, varscan2
- CHST11 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV57988183; called by muse, mutect2, varscan2
- CHST15 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV60562591; called by muse, mutect2, varscan2
- CILP2 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs1047692426, COSV52275318; called by muse, mutect2, varscan2
- CIT | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs773906531, COSV55870133; called by muse, mutect2, varscan2
- CLDN1 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55044210; called by muse, mutect2, varscan2
- CLDN16 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs762831659, COSV53227188; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLEC4A | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV57561876; called by muse, mutect2, varscan2
- CLIP2 | c.910A>G p.M304V | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1221370375, COSV56279476; called by muse, mutect2, varscan2
- CLK2 | c.1294C>T p.R432C (on ENST00000368361 / NM_001294339.2; = p.R431C on NM_003993.4) | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs759554148, COSV56945321, COSV56946468; called by muse, mutect2, varscan2
- CLK2 | c.1043G>A p.R348Q (on ENST00000368361 / NM_001294339.2; = p.R347Q on NM_003993.4) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56945329; called by muse, mutect2
- CLK4 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142631847; called by muse, mutect2, varscan2
- CLPB | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as COSV53630184; called by mutect2, varscan2
- CLSPN | c.1773T>C p.G591= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as COSV52051551; called by muse, mutect2, varscan2
- CLVS1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV57975489; called by muse, mutect2, varscan2
- CMC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs376325635; called by mutect2, varscan2
- CMTM8 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV56777399; called by muse, mutect2, varscan2
- CNOT1 | c.4111G>A p.A1371T | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as COSV55317248; called by muse, mutect2, varscan2
- CNOT11 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56819915; called by muse, mutect2, varscan2
- CNTLN | c.3408A>G p.I1136M | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV52068484; called by muse, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 51/153 reads (33%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61640029; called by muse, mutect2, varscan2
- CNTN5 | c.303del p.F101Lfs*19 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as COSV99678890; called by mutect2, pindel, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.3926C>G p.A1309G | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV62186854; called by muse, mutect2, varscan2
- CNTROB | c.2063A>G p.D688G | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1485430579, COSV66608272; called by muse, mutect2, varscan2
- COG8 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV54742448; called by muse, mutect2, varscan2
- COIL | c.1619T>C p.V540A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV53595084; called by mutect2, varscan2
- COL11A1 | c.3761del p.K1254Rfs*18 | Frame Shift Del (DEL) | VAF 38/142 reads (27%) | catalogued as COSV62184423; called by mutect2, pindel, varscan2
- COL12A1 | c.4924del p.E1642Sfs*5 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | catalogued as COSV59390565; called by mutect2, pindel, varscan2
- COL1A1 | c.1981C>A p.Q661K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as CM137808, COSV56805452; called by muse, varscan2
- COL20A1 | c.1679dup p.R561Efs*168 | Frame Shift Ins (INS) | VAF 5/12 reads (42%) | catalogued as rs761988638; called by mutect2, varscan2
- COL20A1 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755789566, COSV58917944; called by mutect2, varscan2
- COL21A1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55164427; called by muse, mutect2, varscan2
- COL27A1 | c.4054G>T p.G1352C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61926546; called by muse, mutect2, varscan2
- COL6A6 | c.947G>T p.R316M | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV62017207, COSV62026186; called by muse, mutect2, varscan2
- COL6A6 | c.4868A>G p.Q1623R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV62026225; called by muse, mutect2, varscan2
- COL8A2 | c.793del p.E265Sfs*13 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs953375687, COSV57442564; called by mutect2, pindel, varscan2
- COLEC11 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs866636297, COSV52597979; called by muse, mutect2, varscan2
- COPG1 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363716962, COSV59114302; called by muse, mutect2, varscan2
- COQ7 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375432720; called by muse, mutect2, varscan2
- COQ9 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780563472, COSV52645936; called by muse, mutect2, varscan2
- CORO6 | c.1274C>G p.A425G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.06); catalogued as COSV61470971; called by muse, mutect2, varscan2
- CORO6 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs982800544, COSV61470977; called by muse, mutect2, varscan2
- CPA1 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50569553; called by muse, mutect2, varscan2
- CPEB4 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV54171967; called by muse, mutect2, varscan2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs777945397; called by mutect2, varscan2
- CPLX4 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55313728; called by muse, mutect2, varscan2
- CPNE3 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1243542213, COSV52206645; called by muse, mutect2, varscan2
- CPSF6 | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.992); catalogued as COSV57012400, COSV57014857; called by muse, mutect2, varscan2
- CR1 | c.2596T>C p.C866R | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65458486; called by muse, mutect2, varscan2
- CRACDL | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs754312652, COSV67408328; called by muse, mutect2, varscan2
- CRB2 | c.2498G>A p.C833Y | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63503414; called by muse, mutect2, varscan2
- CREBBP | c.6214C>T p.R2072W | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1346068669, COSV52125041; called by muse, mutect2, varscan2
- CREBBP | c.4804C>T p.R1602C | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1313429, COSV52125055; called by muse, mutect2, varscan2
- CRNKL1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.846); catalogued as rs767978683, COSV55630926; called by muse, mutect2, varscan2
- CRP | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.902); catalogued as COSV54813619; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 57/126 reads (45%) | catalogued as rs769538822; called by mutect2, varscan2
- CRY2 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767177340, COSV69888603; called by muse, mutect2, varscan2
- CRYBB2 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV68005446, COSV68005506; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYGB | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV53680314; called by muse, mutect2, varscan2
- CSE1L | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.188); catalogued as rs149344844; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs749326130, COSV65677209, COSV65678130; called by muse, mutect2, varscan2
- CSNK1E | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV63291133; called by mutect2, varscan2
- CSNK1G3 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62054627; called by muse, mutect2, varscan2
- CSTF3 | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 76/212 reads (36%) | catalogued as COSV60611550; called by muse, mutect2, varscan2
- CTAGE1 | c.2222del p.P741Qfs*15 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | catalogued as rs771653179; called by mutect2, pindel, varscan2
- CTSH | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54985177; called by muse, varscan2
- CUBN | c.8754C>T p.S2918= | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as rs773592682, COSV64716643; called by muse, mutect2, varscan2
- CYB5R3 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52809192; called by muse, mutect2, varscan2
- CYB5R3 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs547268043, COSV61545655; called by muse, mutect2, varscan2
- CYB5R4 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as COSV63746582; called by muse, mutect2, varscan2
- CYC1 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1235166309, COSV59644461; called by muse, mutect2, varscan2
- CYFIP2 | c.3424G>A p.V1142I (on ENST00000616178 / NM_001291722.2; = p.V1117I on NM_014376.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as rs764457342, COSV59039121; called by muse, mutect2, varscan2
- CYLD | c.2266A>C p.M756L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV61094851; called by muse, mutect2, varscan2
- CYP17A1 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as CM880019, COSV64004948; called by muse, mutect2, varscan2
- CYP26A1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV56418456; called by muse, mutect2, varscan2
- CYP4F11 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs758162397, COSV56127244; called by muse, mutect2
- CYREN | c.389del p.G130Vfs*19 | Frame Shift Del (DEL) | VAF 25/138 reads (18%) | catalogued as rs753942205; called by mutect2, pindel, varscan2
- CYSLTR1 | c.671del p.N224Ifs*9 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs766746913; called by mutect2, varscan2
- CYTH1 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776237586, COSV63120621; called by muse, mutect2, varscan2
- CYTH2 | c.1052A>G p.H351R (on ENST00000427476; = p.H350R on NM_004228.7) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57309411; called by muse, mutect2
- DAGLB | c.2011G>A p.V671M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs148435637; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DBNL | c.1198G>T p.G400C (on ENST00000448521 / NM_001014436.3; = p.G401C on NM_014063.7) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV51978328; called by muse, mutect2, varscan2
- DCAF6 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as rs959403927, COSV56579238; called by muse, mutect2, varscan2
- DCLK2 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56205022; called by muse, mutect2, varscan2
- DCLK3 | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV69363264; called by muse, mutect2, varscan2
- DCST2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV55052058; called by muse, mutect2
- DCT | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV65469281; called by muse, mutect2, varscan2
- DCTN1 | c.2754del p.S919Afs*25 | Frame Shift Del (DEL) | VAF 36/123 reads (29%) | catalogued as rs1229620804; called by mutect2, pindel, varscan2
- DDB1 | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.151); catalogued as COSV57103026; called by muse, mutect2, varscan2
- DDIAS | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61272262; called by muse, mutect2, varscan2
- DDIT4L | c.453G>T p.R151S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV56767387; called by muse, mutect2, varscan2
- DDX27 | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874758; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DDX50 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.168); catalogued as rs765452017, COSV65292329; called by muse, mutect2, varscan2
- DDX53 | c.246A>G p.I82M | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV60069162; called by muse, mutect2, varscan2
- DDX56 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs556884834, COSV51835960; called by muse, mutect2, varscan2
- DEFB112 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV59182622; called by muse, mutect2, varscan2
- DELE1 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52005046; called by muse, mutect2, varscan2
- DENND2A | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747667851, COSV52051964; called by muse, mutect2, varscan2
- DENND2B | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 32/353 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58203956; called by muse, mutect2
- DENND3 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.35); catalogued as rs559179440, COSV52802702; called by muse, mutect2, varscan2
- DENND4B | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63409449; called by muse, mutect2, varscan2
- DEPDC1B | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV54010313; called by muse, mutect2, varscan2
- DGKD | c.514G>A p.A172T (on ENST00000264057 / NM_152879.3; = p.A128T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs779077238, COSV51049921; called by muse, mutect2, varscan2
- DGKQ | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746587352, COSV53279029; called by muse, mutect2, varscan2
- DHX30 | c.1490T>C p.V497A (on ENST00000445061 / NM_138615.3; = p.V458A on NM_014966.3) | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV53137939; called by muse, mutect2, varscan2
- DHX35 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs377277906, COSV52670522; called by muse, mutect2, varscan2
- DHX36 | c.368+2T>C p.X123_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | catalogued as COSV57672918; called by muse, mutect2, varscan2
- DHX38 | c.3460G>A p.A1154T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV51698185; called by muse, mutect2, varscan2
- DHX40 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1335765079, COSV52067831; called by muse, mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs755069320; called by mutect2, varscan2
- DIDO1 | c.1425del p.E476Rfs*4 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | catalogued as rs762377755; called by mutect2, varscan2
- DIP2B | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as rs777760335, COSV56584599; called by muse, mutect2, varscan2
- DIPK2A | c.199T>C p.F67L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.971); catalogued as COSV100237134, COSV59857426; called by muse, mutect2, varscan2
- DIRAS1 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60215684; called by muse, mutect2, varscan2
- DISP2 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.095); catalogued as COSV51122883, COSV99139998; called by muse, mutect2, varscan2
- DKK4 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV55182591; called by muse, mutect2, varscan2
- DLG5 | c.4723C>T p.R1575C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1382546442, COSV64947365; called by muse, mutect2, varscan2
- DMD | c.2909C>A p.T970N | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.059); catalogued as COSV63757466; called by muse, mutect2, varscan2
- DMXL1 | c.4098T>A p.N1366K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV60712500; called by muse, mutect2, varscan2
- DNA2 | c.2897T>C p.V966A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV64428667; called by muse, mutect2, varscan2
- DNAH1 | c.10886G>A p.R3629H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202058333; called by muse, mutect2, varscan2
- DNAH10 | c.3833T>C p.V1278A (on ENST00000409039; = p.V1217A on NM_207437.3) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV68994458; called by muse, mutect2
- DNAH11 | c.4145G>A p.G1382D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60957578; called by muse, mutect2, varscan2
- DNAH11 | c.6183T>A p.D2061E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV60957588; called by muse, mutect2, varscan2
- DNAH17 | c.12121C>T p.R4041C | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs151281798; called by muse, mutect2, varscan2
- DNAH2 | c.6589G>A p.A2197T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs371514138; called by muse, mutect2, varscan2
- DNAH3 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54524445; called by muse, mutect2, varscan2
- DNAH5 | c.10640G>A p.R3547Q | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs779977337, COSV54218943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.5369T>A p.V1790D | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV56766749; called by muse, mutect2, varscan2
- DNAH9 | c.10690C>T p.P3564S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52351884; called by muse, mutect2, varscan2
- DNAI2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56757871; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 37/171 reads (22%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJC1 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV65411210; called by muse, mutect2, varscan2
- DNAJC16 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs763316438, COSV65448609; called by muse, mutect2, varscan2
- DNAJC30 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56095085; called by muse, mutect2, varscan2
- DNMT3B | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 7/101 reads (7%) | catalogued as COSV52417776; called by muse, mutect2
- DNMT3B | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM002946, COSV52415711; called by muse, mutect2, varscan2
- DOCK4 | c.5621C>T p.A1874V | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV70237313, COSV70240690; called by muse, mutect2, varscan2
- DOCK5 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52402750; called by muse, mutect2
- DOK7 | c.1156T>C p.C386R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV60772334; called by muse, mutect2, varscan2
- DOK7 | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs377555406, COSV60772347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOP1B | c.984dup p.E329* | Frame Shift Ins (INS) | VAF 28/74 reads (38%) | catalogued as rs1414264989; called by mutect2, varscan2
- DOP1B | c.5121G>A p.K1707= | Splice Region (SNP) | VAF 19/61 reads (31%) | catalogued as rs1183506811, COSV67693525; called by muse, mutect2, varscan2
- DPP3 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 70/164 reads (43%) | catalogued as COSV64756898; called by muse, mutect2, varscan2
- DPP6 | c.1412A>G p.N471S (on ENST00000377770 / NM_001364500.2; = p.N409S on NM_001936.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as COSV59615541; called by muse, mutect2, varscan2
- DPPA4 | c.444del p.K148Nfs*2 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs762470455; called by mutect2, varscan2
- DPYSL5 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV56512337; called by muse, mutect2, varscan2
- DPYSL5 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs755205638, COSV56512346, COSV99982937; called by muse, mutect2, varscan2
- DRC1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as rs756078948, COSV56530002; called by muse, mutect2, varscan2
- DRC7 | c.1373T>G p.L458R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61054896; called by muse, mutect2, varscan2
- DROSHA | c.1355T>C p.L452S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100757833; called by muse, mutect2, varscan2
- DSCAM | c.5251A>T p.T1751S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV68027358; called by muse, mutect2, varscan2
- DSCAML1 | c.4370C>T p.S1457L (on ENST00000321322; = p.S1397L on NM_020693.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs759021316, COSV58391423; called by muse, mutect2, varscan2
- DSCC1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs750237304, COSV58087217; called by muse, mutect2, varscan2
- DSE | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as COSV59064294; called by muse, mutect2, varscan2
- DSG2 | c.3224C>T p.T1075M | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs943749481, COSV55199531; called by muse, mutect2, varscan2
- DSP | c.3501G>T p.K1167N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1181074160, COSV65793055; called by muse, mutect2, varscan2
- DST | c.21635T>C p.L7212P (on ENST00000361203 / NM_001374722.1; = p.L4909P on NM_015548.5) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766884642, COSV55016832; called by muse, mutect2, varscan2
- DTX1 | c.1641G>A p.V547= | Splice Region (SNP) | VAF 12/32 reads (38%) | catalogued as COSV55656325; called by muse, mutect2, varscan2
- DTX2 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV99991199; called by muse, mutect2, varscan2
- DUOX1 | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV58481445; called by muse, mutect2, varscan2
- DUS3L | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763111241, COSV57832094; called by muse, mutect2, varscan2
- DUSP12 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV63411194; called by muse, mutect2, varscan2
- DUSP15 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs771404423, COSV54066380; called by muse, mutect2, varscan2
- DUSP26 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs745976867, COSV56361442; called by muse, mutect2, varscan2
- DVL3 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV57456296; called by muse, mutect2, varscan2
- DYRK3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV65606397; called by muse, mutect2, varscan2
- DZIP3 | c.1643A>G p.D548G | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as rs896721500, COSV64312200; called by muse, mutect2, varscan2
- E2F7 | c.177del p.K59Nfs*29 | Frame Shift Del (DEL) | VAF 41/102 reads (40%) | catalogued as rs771114476; called by mutect2, varscan2
- E4F1 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57039246; called by muse, mutect2, varscan2
- EBF1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.14); catalogued as COSV58179858; called by muse, mutect2, varscan2
- EBF3 | c.946C>G p.P316A (on ENST00000355311 / NM_001375392.1; = p.P307A on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV62475475, COSV99051406; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 31/62 reads (50%) | catalogued as rs369293935; called by mutect2, varscan2
- ECSIT | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1414192731, COSV52938608; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs918065407, COSV100668565, COSV62568105; called by muse, mutect2, varscan2
- EEF1AKNMT | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV62283121; called by muse, mutect2, varscan2
- EEPD1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs540375594, COSV54198667; called by muse, mutect2, varscan2
- EFCAB5 | c.3832T>C p.C1278R | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57930551; called by muse, mutect2, varscan2
- EFL1 | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV51603375, COSV51608329, COSV99188868; called by muse, mutect2, varscan2
- EFTUD2 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV68182414; called by muse, mutect2, varscan2
- EGFR | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs749783044, COSV51803089; called by muse, mutect2, varscan2
- EIF2AK1 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52239792; called by muse, mutect2
- EIF2B1 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs779302767, COSV71194221; called by muse, mutect2, varscan2
- EIF2D | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs782353865, COSV55113787; called by muse, mutect2, varscan2
- EIF3M | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV58799016; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EIF5B | c.2751C>T p.N917= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as COSV56813350; called by muse, mutect2, varscan2
- ELAC1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV53996653; called by muse, mutect2, varscan2
- ELFN2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs371574699, COSV68744666; called by muse, mutect2, varscan2
- ELOA | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV69310323; called by muse, mutect2, varscan2
- ELOVL1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332091166, COSV60522197; called by muse, mutect2, varscan2
- ELP1 | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV65897910; called by muse, mutect2
- ELP1 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV65897914; called by muse, mutect2, varscan2
- EML1 | c.1345A>G p.N449D | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV51745838; called by muse, mutect2, varscan2
- EML2 | c.1697T>A p.I566N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV55599842; called by muse, mutect2
- ENTR1 | c.1071G>A p.A357= (on ENST00000357365 / NM_001039707.2; = p.A334= on NM_006643.4) | Splice Region (SNP) | VAF 81/199 reads (41%) | catalogued as rs567797172, COSV53741690; called by muse, mutect2, varscan2
- EP400 | c.6877C>T p.R2293C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433414794, COSV57763285; called by muse, mutect2, varscan2
- EPB41 | c.590T>C p.L197S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV58047286; called by muse, mutect2
- EPB41 | c.1744del p.T582Qfs*11 (on ENST00000343067 / NM_001166005.2; = p.T373Qfs*11 on NM_004437.4) | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | catalogued as COSV58042400; called by mutect2, pindel, varscan2
- EPB41L4B | c.1878+1G>A p.X626_splice | Splice Site (SNP) | VAF 46/103 reads (45%) | catalogued as COSV65803245; called by muse, mutect2, varscan2
- EPB42 | c.862G>A p.V288M (on ENST00000441366 / NM_001114134.2; = p.V318M on NM_000119.3) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765302713, COSV100281810, COSV55749292; called by muse, mutect2, varscan2
- EPHA1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs745810214, COSV51971697; called by muse, mutect2, varscan2
- EPHA2 | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs140398645; called by muse, mutect2, varscan2
- EPHA3 | c.1957A>G p.K653E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60707549; called by muse, mutect2, varscan2
- EPHA3 | c.2774C>T p.T925I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60704930, COSV60707559; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 26/165 reads (16%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- EPS15 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV65531211; called by muse, mutect2, varscan2
- EPS15 | c.165+2T>C p.X55_splice | Splice Site (SNP) | VAF 42/104 reads (40%) | catalogued as COSV65531217; called by muse, mutect2, varscan2
- ERBB2 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.997); catalogued as COSV54071524; called by muse, mutect2, varscan2
- ERC1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs886848143, COSV61695255; called by muse, varscan2
- ERC1 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as rs778101125, COSV61695259; called by muse, mutect2, varscan2
- ERC2 | c.2456C>T p.T819I | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV55610492, COSV55625287; called by muse, mutect2, varscan2
- ERCC3 | c.1762del p.E588Kfs*23 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as rs770925947, COSV53428702; called by mutect2, pindel, varscan2
- ERCC6 | c.2838G>T p.E946D | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63390423; called by muse, mutect2, varscan2
- ERICH3 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV58607746; called by muse, mutect2, varscan2
- ERICH6 | c.460A>G p.R154G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV55800719; called by muse, mutect2, varscan2
- ERLEC1 | c.1227-2A>G p.X409_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV51751912; called by mutect2, varscan2
- ESPNL | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs535747214, COSV58034846; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs775950025; called by mutect2, varscan2
- ETNK1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs749131482, COSV56885971; called by muse, mutect2, varscan2
- ETS1 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs768471010, COSV60093713; called by mutect2, varscan2
- ETV3L | c.341G>T p.R114M | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71901106; called by muse, mutect2, varscan2
- EXD1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527801980, COSV59254288; called by muse, mutect2, varscan2
- EXD3 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs759878241, COSV59807823; called by muse, mutect2, varscan2
- EXOC2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.053); catalogued as rs779755243, COSV57865386; called by muse, mutect2, varscan2
- EXOC3L1 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.419); catalogued as COSV52046540; called by muse, mutect2, varscan2
- EXOC3L1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58874841; called by muse, mutect2, varscan2
- EYA3 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65816745; called by muse, mutect2, varscan2
- EYA4 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62052770; called by muse, mutect2, varscan2
- F13A1 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.841); catalogued as COSV53559159; called by muse, mutect2, varscan2
- F5 | c.4042C>A p.L1348I | Missense Mutation (SNP) | VAF 67/403 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs1485283798, COSV63124463; called by muse, mutect2, varscan2
- FAM111A | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs202134817; called by muse, mutect2, varscan2
- FAM111B | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV59112079; called by muse, mutect2, varscan2
- FAM135A | c.368C>T p.S123L (on ENST00000370479 / NM_001351599.1; = p.S80L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs149122763, COSV99524985; called by muse, mutect2, varscan2
- FAM151A | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56364376; called by muse, mutect2, varscan2
- FAM155B | c.494dup p.L166Sfs*5 | Frame Shift Ins (INS) | VAF 23/68 reads (34%) | catalogued as rs769524017; called by mutect2, varscan2
- FAM160A2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs370295056, COSV56411685; called by muse, mutect2, varscan2
- FAM160B1 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as rs755167531, COSV65088232; called by muse, mutect2, varscan2
- FAM166B | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377595292; called by muse, mutect2, varscan2
- FAM172A | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV67937831; called by muse, mutect2, varscan2
- FAM174A | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.027); catalogued as COSV57063562; called by muse, mutect2, varscan2
- FAM186B | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57721678; called by muse, mutect2, varscan2
- FAM187B | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.081); catalogued as rs377174051; called by muse, mutect2, varscan2
- FAM189B | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755193895, COSV56945308; called by muse, mutect2, varscan2
- FAM209B | c.78A>T p.R26S | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV100991033; called by muse, mutect2, varscan2
- FAM214B | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV59716298; called by muse, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM221A | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV61387885; called by muse, mutect2, varscan2
- FAM24B | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 37/79 reads (47%) | catalogued as COSV59026792; called by muse, mutect2, varscan2
- FAM47B | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61454146, COSV61455865; called by muse, varscan2
- FAM47B | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.695); catalogued as COSV61454154; called by muse, varscan2
- FAM47B | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61454159; called by muse, mutect2, varscan2
- FAM47B | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs201715948, COSV61453537; called by muse, mutect2, varscan2
- FAM47C | c.1787del p.P596Rfs*229 | Frame Shift Del (DEL) | VAF 44/196 reads (22%) | catalogued as COSV63724780; called by pindel, varscan2
- FAM71F1 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV59373790; called by muse, mutect2, varscan2
- FAM76A | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1469817961, COSV50548807; called by muse, mutect2, varscan2
- FAM78B | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100597878, COSV57977513; called by muse, mutect2
- FAM83B | c.79T>C p.W27R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV60922435; called by muse, mutect2, varscan2
- FAM83C | c.377del p.P126Qfs*51 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as rs768032945; called by mutect2, pindel, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FANK1 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs199770819; called by muse, mutect2, varscan2
- FARS2 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs369015058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTK | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52540179; called by muse, mutect2, varscan2
- FASTK | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs779155034, COSV52540191; called by muse, mutect2, varscan2
- FASTK | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV52540204; called by muse, mutect2, varscan2
- FAT1 | c.6197T>C p.V2066A | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.307); catalogued as COSV71674333; called by muse, mutect2, varscan2
- FBN1 | c.8438G>A p.S2813N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV57317847; called by muse, mutect2, varscan2
- FBN2 | c.5621A>G p.Y1874C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52515848; called by muse, mutect2, varscan2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs772353703; called by mutect2, pindel, varscan2
- FBXL13 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763963204, COSV57538615; called by muse, mutect2, varscan2
- FBXO10 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.679); catalogued as rs937038245, COSV52833146; called by muse, mutect2, varscan2
- FBXO24 | c.96dup p.K33Efs*118 (on ENST00000241071 / NM_033506.3; = p.K71Efs*118 on NM_012172.5) | Frame Shift Ins (INS) | VAF 17/140 reads (12%) | catalogued as rs1255600690; called by pindel, varscan2
- FBXO24 | c.962del p.G321Efs*69 (on ENST00000241071 / NM_033506.3; = p.G359Efs*69 on NM_012172.5) | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | catalogued as rs1412286983; called by mutect2, pindel, varscan2
- FBXO25 | c.199del p.R67Gfs*44 (on ENST00000382824 / NM_183421.2; = p.G17Efs*6 on NM_012173.3) | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs758426962; called by mutect2, pindel, varscan2
- FBXO32 | c.1046T>C p.F349S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV54891157; called by muse, mutect2, varscan2
- FBXO38 | c.3262T>C p.Y1088H (on ENST00000340253 / NM_205836.3; = p.Y1013H on NM_030793.5) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57028132; called by muse, mutect2, varscan2
- FBXO41 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs771960976, COSV54584631, COSV99721740; called by muse, mutect2, varscan2
- FBXO46 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1163574892, COSV58348694; called by muse, mutect2
- FBXW4 | c.1600T>A p.S534T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV58706942, COSV58708079; called by muse, mutect2, varscan2
- FBXW4 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV58708092; called by muse, mutect2, varscan2
- FBXW5 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56403074; called by muse, mutect2, varscan2
- FCGBP | c.3107C>T p.T1036M | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as rs751928200; called by muse, mutect2, varscan2
- FCHSD2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs775149903, COSV60810109; called by muse, mutect2, varscan2
- FCMR | c.82del p.E28Sfs*17 | Frame Shift Del (DEL) | VAF 43/177 reads (24%) | catalogued as rs779983414, COSV65567121; called by mutect2, pindel, varscan2
- FCN2 | c.267C>T p.N89= | Splice Region (SNP) | VAF 22/56 reads (39%) | catalogued as rs775318175, COSV52476820; called by muse, mutect2, varscan2
- FCRL2 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs530956948, COSV63833677; called by muse, mutect2, varscan2
- FCSK | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs747072933, COSV55371200; called by muse, mutect2, varscan2
- FDXR | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53122205; called by muse, mutect2, varscan2
- FER1L6 | c.1242A>T p.K414N | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV67550206; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as rs747094222, COSV67548414; called by mutect2, varscan2
- FER1L6 | c.5125+1G>A p.X1709_splice | Splice Site (SNP) | VAF 16/37 reads (43%) | catalogued as COSV67550208, COSV67552170; called by muse, mutect2, varscan2
- FERMT2 | c.455del p.K152Rfs*4 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs766229731; called by mutect2, varscan2
- FEZF2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV51863099; called by muse, mutect2, varscan2
- FGF6 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs373061794; called by muse, mutect2, varscan2
- FGFR4 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs754621505, COSV52804196; called by muse, mutect2, varscan2
- FGR | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV64969531, COSV64969748; called by muse, mutect2, varscan2
- FHL1 | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs749585308, COSV61781217; called by muse, mutect2, varscan2
- FHL5 | c.277T>C p.C93R | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58737762; called by muse, mutect2, varscan2
- FHOD1 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.099); catalogued as rs1217158444, COSV50761134; called by muse, mutect2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 39/89 reads (44%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FHOD3 | c.4054G>A p.D1352N (on ENST00000359247 / NM_001281739.3; = p.D1369N on NM_025135.5) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57174200; called by muse, mutect2, varscan2
- FIBP | c.1063C>T p.R355C (on ENST00000338369 / NM_198897.2; = p.R348C on NM_004214.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as rs1000765021, COSV57172445; called by muse, mutect2, varscan2
- FIP1L1 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.585); catalogued as rs765081392, COSV60996758; called by muse, mutect2, varscan2
- FKBP8 | c.569C>T p.P190L (on ENST00000222308 / NM_001308373.2; = p.P191L on NM_012181.5) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs373750416; called by muse, mutect2, varscan2
- FKBP8 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs1489317297, COSV55892544; called by muse, mutect2, varscan2
- FLG | c.8312A>G p.Q2771R | Missense Mutation (SNP) | VAF 158/1226 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs745721128, COSV64242428; called by muse, mutect2, varscan2
- FLG | c.1609A>C p.N537H | Missense Mutation (SNP) | VAF 534/884 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs770898927, COSV64242435; called by muse, mutect2, varscan2
- FLII | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58945248; called by muse, mutect2, varscan2
- FLNA | c.5881T>C p.S1961P (on ENST00000369850 / NM_001110556.2; = p.S1953P on NM_001456.3) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV61043784; called by muse, mutect2, varscan2
- FLNC | c.3422C>A p.P1141H | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57950856, COSV57956561; called by muse, mutect2, varscan2
- FLRT3 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1343984896, COSV53990183; called by muse, mutect2, varscan2
- FLT4 | c.1762C>A p.L588M | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56109551; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV56098414; called by mutect2, varscan2
- FLVCR2 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs139495418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN1 | c.2437C>T p.L813F (on ENST00000616417 / NM_001277313.2; = p.L590F on NM_001103184.4) | Missense Mutation (SNP) | VAF 138/341 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs771163775, COSV57923676; called by muse, mutect2, varscan2
- FMN2 | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV60431882; called by muse, mutect2
- FN1 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV60553927; called by muse, mutect2
- FOCAD | c.5005-1G>T p.X1669_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | catalogued as COSV58099885; called by muse, mutect2, varscan2
- FOXD4L5 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV101073285; called by muse, mutect2, varscan2
- FOXE1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.181); catalogued as COSV64300493; called by muse, mutect2, varscan2
- FOXM1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs759317474, COSV100700922, COSV61206147; called by muse, mutect2, varscan2
- FOXO4 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as rs749755171, COSV58575316; called by muse, mutect2, varscan2
- FPGS | c.228G>T p.L76F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV64675686; called by muse, mutect2, varscan2
- FRMD4A | c.2921C>T p.T974I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs765447123, COSV62266361; called by mutect2, varscan2
- FRMD8 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.552); catalogued as COSV58212761; called by muse, mutect2, varscan2
- FRMPD2 | c.1844C>T p.T615I | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.292); catalogued as COSV59718386; called by muse, mutect2, varscan2
- FRY | c.3242A>G p.D1081G | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV66570816; called by muse, mutect2, varscan2
- FRY | c.7793G>A p.R2598H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs577820940, COSV66566793; called by muse, mutect2, varscan2
- FRYL | c.2953C>T p.R985* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as rs777104898, COSV51948237; called by muse, mutect2, varscan2
- FST | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56815299; called by muse, mutect2, varscan2
- FUT5 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139667433, COSV53136724; called by muse, mutect2, varscan2
- FUZ | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 166/594 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs370940328; called by muse, varscan2
- FZD1 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 101/423 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV55311139; called by muse, mutect2, varscan2
- FZD10 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.533); catalogued as COSV57473718; called by muse, mutect2, varscan2
- FZD6 | c.1521del p.F507Lfs*25 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | catalogued as COSV62470622; called by mutect2, pindel, varscan2
- GAB2 | c.2016G>T p.K672N (on ENST00000361507 / NM_080491.3; = p.K634N on NM_012296.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV60868153, COSV60869638; called by muse, mutect2, varscan2
- GAB2 | c.1169A>G p.N390S (on ENST00000361507 / NM_080491.3; = p.N352S on NM_012296.3) | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750289098, COSV60868161; called by muse, mutect2, varscan2
- GABPB1 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1357586939, COSV55015068; called by muse, mutect2, varscan2
- GABRA1 | c.785T>C p.I262T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV99196302; called by muse, mutect2, varscan2
- GABRA1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50105564; called by muse, varscan2
- GABRA2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62913387; called by muse, mutect2, varscan2
- GABRA3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs139179813, COSV64799220; called by muse, mutect2, varscan2
- GABRD | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1270464006, COSV66080741; called by muse, mutect2, varscan2
2,638 further variants in this file (1,841 protein-altering or splice-affecting, 727 silent, 70 other) are not listed here.
